Somatic mutation profile of tumor specimen TCGA-DK-AA75-01A (aliquot TCGA-DK-AA75-01A-11D-A391-08) from TCGA case TCGA-DK-AA75, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 82.4 years (30,090 days).
Specimen TCGA-DK-AA75-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4fd320c-270b-4251-9f2d-4877ba556771.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-AA75-10A (Blood Derived Normal), aliquot TCGA-DK-AA75-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/527882ff-d0ee-484d-86fc-c597f2cf813d

The open-access MAF lists 572 somatic variants for this specimen: 394 protein-altering or splice-affecting, 158 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 344, Silent 158, Nonsense Mutation 33, Splice Region 6, Intron 6, Splice Site 5, RNA 5, 5'Flank 3, Frame Shift Ins 2, Frame Shift Del 2, 3'Flank 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASS | c.1925C>G p.S642* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as rs587777124, CM1310230, COSV100741734; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 42/69 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, varscan2
- ABCG1 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV101268817; called by muse, mutect2, varscan2
- ACIN1 | c.2141C>T p.S714L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1361799292, COSV52973301, COSV99400150; called by muse, mutect2, varscan2
- ACO1 | c.2113G>C p.E705Q | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV59376850; called by muse, mutect2, varscan2
- ACOX1 | c.1837C>T p.Q613* | Nonsense Mutation (SNP) | VAF 71/173 reads (41%) | catalogued as rs1417833433, COSV99503404; called by muse, mutect2, varscan2
- ACOX3 | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 70/154 reads (45%) | catalogued as COSV100711874; called by muse, mutect2, varscan2
- ACSBG1 | c.1007A>G p.Y336C | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV51903388; called by muse, mutect2, varscan2
- ACTN1 | c.749C>G p.S250C | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV51988567, COSV51997587; called by muse, mutect2, varscan2
- ACTN2 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | catalogued as COSV63976546; called by muse, mutect2, varscan2
- ADAM10 | c.1754C>T p.S585F | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV53049302; called by muse, mutect2, varscan2
- ADCY10 | c.4753G>A p.V1585I | Missense Mutation (SNP) | VAF 138/191 reads (72%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV63238556; called by muse, mutect2, varscan2
- ADGRB3 | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as rs929926249, COSV53234819; called by muse, mutect2, varscan2
- AFF3 | c.3397C>T p.Q1133* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as COSV100418396; called by muse, mutect2, varscan2
- AHNAK | c.13093G>C p.D4365H | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57203719; called by muse, mutect2, varscan2
- AHR | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV99619472; called by muse, mutect2
- AKAP9 | c.4141C>T p.P1381S | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV62338770; called by muse, mutect2, varscan2
- AMN | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV54486094; called by muse, mutect2
- AMY2A | c.80C>A p.S27Y | Missense Mutation (SNP) | VAF 40/346 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV101340624; called by muse, mutect2, varscan2
- ANKAR | c.2608C>T p.L870F | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55609455; called by muse, mutect2
- ANKRD17 | c.5752C>T p.P1918S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.026); catalogued as COSV58215475; called by muse, mutect2, varscan2
- ANKRD52 | c.3064C>T p.P1022S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV57282234; called by muse, mutect2, varscan2
- AOPEP | c.170A>G p.N57S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52914646; called by muse, mutect2, varscan2
- AOPEP | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52914668; called by muse, mutect2, varscan2
- AP5B1 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs777872119, COSV57502196; called by muse, varscan2
- AP5B1 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.402); catalogued as COSV57502207; called by muse, mutect2, varscan2
- AP5B1 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.107); catalogued as COSV57502214; called by muse, mutect2
- ARHGAP11B | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.17); catalogued as COSV101451776; called by mutect2, varscan2
- ARHGEF17 | c.3770G>C p.S1257T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as COSV55229430; called by muse, mutect2, varscan2
- ARID2 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV57596050, COSV57603262; called by muse, mutect2, varscan2
- ARPC4 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV99809433; called by muse, mutect2
- ASCC3 | c.509C>A p.S170* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | catalogued as COSV100225454; called by muse, mutect2
- ASPM | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 167/221 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs772380769, COSV54124697, COSV99660829; called by muse, mutect2, varscan2
- ATAD2B | c.309A>T p.K103N | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.197); catalogued as COSV53195175; called by muse, mutect2, varscan2
- ATAD5 | c.3082G>T p.E1028* | Nonsense Mutation (SNP) | VAF 34/93 reads (37%) | catalogued as COSV100429787; called by muse, mutect2, varscan2
- ATE1 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1298716834, COSV56433366; called by muse, mutect2, varscan2
- ATP10A | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1449438862, COSV63513598; called by muse, mutect2, varscan2
- BAG2 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1197878317, COSV100674795; called by muse, mutect2, varscan2
- BANK1 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV59838386; called by muse, mutect2, varscan2
- BCL2L1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56966084; called by muse, mutect2, varscan2
- BLNK | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as COSV56408909; called by muse, mutect2, varscan2
- BRAT1 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV61394086; called by muse, mutect2, varscan2
- BRD1 | c.2861G>T p.R954L (on ENST00000216267 / NM_001349940.1; = p.R1085L on NM_001304808.3) | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1193081900, COSV53454794; called by muse, mutect2, varscan2
- BRINP3 | c.1894C>A p.R632S | Missense Mutation (SNP) | VAF 24/337 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.283); catalogued as COSV66513604, COSV66513646; called by muse, mutect2
- BRPF3 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60205937; called by muse, mutect2, varscan2
- BTBD16 | c.682A>G p.T228A | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.083); catalogued as rs746545674, COSV53260704; called by muse, mutect2, varscan2
- BUB1 | c.1427A>G p.Q476R | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57061237; called by muse, mutect2, varscan2
- C10orf71 | c.2067G>C p.Q689H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV60504549, COSV60513920; called by muse, mutect2, varscan2
- C14orf39 | c.1157G>A p.R386K | Missense Mutation (SNP) | VAF 69/117 reads (59%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV58779525; called by muse, mutect2, varscan2
- C22orf23 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as COSV50777656; called by muse, mutect2, varscan2
- C4B | c.3409G>A p.E1137K | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV101312158; called by muse, mutect2, varscan2
- C7orf31 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); catalogued as rs199915320, COSV52216055; called by muse, mutect2, varscan2
- CACNA1B | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs1034554149, COSV99495105; called by muse, mutect2, varscan2
- CACNA1C | c.2140G>A p.D714N | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.995); catalogued as rs1296416490, COSV59697175; called by muse, mutect2, varscan2
- CAMKK1 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV50113995; called by muse, mutect2, varscan2
- CAMKK2 | c.1609C>T p.R537* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as rs746809158, COSV100242749; called by muse, mutect2, varscan2
- CAPN13 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.918); catalogued as COSV54428402; called by muse, mutect2, varscan2
- CARMIL2 | c.870A>T p.R290= | Splice Region (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100576016; called by muse, mutect2, varscan2
- CCDC158 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs1180426053, COSV66355196; called by muse, mutect2, varscan2
- CCDC178 | c.2108G>C p.R703T (on ENST00000383096 / NM_001105528.3; = p.R665T on NM_198995.3) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.215); catalogued as COSV100286036, COSV55759557; called by muse, mutect2, varscan2
- CCDC178 | c.2057A>T p.D686V (on ENST00000383096 / NM_001105528.3; = p.D648V on NM_198995.3) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as COSV55759571; called by muse, mutect2, varscan2
- CCDC90B | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as rs1266650740, COSV52623421; called by muse, mutect2
- CCN1 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.224); catalogued as rs768362037, COSV71704266; called by muse, mutect2, varscan2
- CCPG1 | c.1115G>A p.R372K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV60524036; called by muse, mutect2, varscan2
- CD248 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV60935726; called by muse, mutect2, varscan2
- CD52 | c.55A>G p.I19V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as COSV57483799; called by muse, mutect2, varscan2
- CDH4 | c.1634C>G p.S545* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | catalogued as COSV100848627; called by muse, mutect2
- CDHR1 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60559551; called by muse, mutect2, varscan2
- CDK13 | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV51696399; called by muse, mutect2
- CDK5RAP1 | c.1428G>A p.M476I (on ENST00000357886 / NM_001365728.1; = p.M462I on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV59425843; called by muse, mutect2, varscan2
- CEACAM1 | c.84G>A p.W28* | Nonsense Mutation (SNP) | VAF 24/164 reads (15%) | catalogued as COSV50727466; called by muse, mutect2, varscan2
- CELF3 | c.232A>T p.N78Y | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.322); catalogued as COSV51881544; called by muse, mutect2, varscan2
- CELF3 | c.231G>A p.M77I | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV51881563; called by muse, mutect2, varscan2
- CELSR1 | c.4144G>A p.E1382K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1157856047, COSV53091928; called by muse, mutect2
- CEP76 | c.1189G>C p.V397L | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV50865521; called by muse, mutect2, varscan2
- CES4A | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1366345637, COSV58651552; called by muse, mutect2, varscan2
- CFAP161 | c.296T>C p.I99T | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV54428374; called by muse, mutect2, varscan2
- CFHR5 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 104/162 reads (64%) | SIFT tolerated (0.21); PolyPhen benign (0.173); catalogued as COSV56818144; called by muse, varscan2
- CFL2 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV53310945; called by muse, mutect2, varscan2
- CGN | c.3452C>G p.S1151C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV54967993; called by muse, mutect2, varscan2
- CHPF2 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV50389047; called by muse, mutect2, varscan2
- CHRNG | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as COSV101263907; called by muse, mutect2, varscan2
- CIT | c.4951G>C p.E1651Q | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as COSV55859959; called by muse, mutect2, varscan2
- CKAP5 | c.3122C>T p.A1041V | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV56364140; called by muse, mutect2, varscan2
- CLN3 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs747526330, COSV61104811; called by muse, mutect2, varscan2
- CMPK1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64101663; called by muse, mutect2, varscan2
- CMYA5 | c.5635G>A p.E1879K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as COSV71404087; called by muse, mutect2, varscan2
- CNKSR2 | c.2755G>C p.A919P | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV65330122; called by muse, mutect2, varscan2
- CNST | c.1664G>A p.C555Y | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV63621463; called by muse, mutect2, varscan2
- CNTNAP4 | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 7/66 reads (11%) | catalogued as COSV100269367; called by muse, mutect2
- COA3 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.089); catalogued as COSV55901505; called by muse, mutect2, varscan2
- COG6 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 27/67 reads (40%) | catalogued as COSV100742713; called by muse, mutect2, varscan2
- COL21A1 | c.515C>G p.S172* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99778062; called by muse, mutect2, varscan2
- COL22A1 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs777346782, COSV57323338; called by mutect2, varscan2
- CORO2A | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778762457, COSV59661972; called by muse, mutect2, varscan2
- CREB3L4 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.192); catalogued as COSV55209223; called by muse, mutect2
- CRLF3 | c.596G>C p.W199S | Missense Mutation (SNP) | VAF 80/157 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60835208; called by muse, mutect2, varscan2
- CRMP1 | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs371645916; called by muse, mutect2, varscan2
- CRNKL1 | c.2518G>C p.D840H | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.769); catalogued as COSV58548066; called by muse, mutect2, varscan2
- CSRNP2 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372606177; called by muse, mutect2, varscan2
- CTDSP2 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101143062, COSV66079738; called by muse, mutect2, varscan2
- CUL4B | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV60684689; called by muse, mutect2, varscan2
- CXCL1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67611532; called by muse, mutect2, varscan2
- CYP27B1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs775461299, COSV57347787; called by muse, mutect2, varscan2
- CYRIB | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.311); catalogued as rs779014064, COSV67828524; called by muse, mutect2, varscan2
- DDX17 | c.1199G>C p.S400T | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.05); catalogued as COSV53250653; called by muse, mutect2, varscan2
- DEPDC4 | c.159A>G p.G53= | Splice Region (SNP) | VAF 11/33 reads (33%) | catalogued as COSV54553034; called by muse, mutect2, varscan2
- DHRS3 | c.198T>C p.I66= | Splice Region (SNP) | VAF 15/67 reads (22%) | catalogued as COSV66107580; called by muse, mutect2, varscan2
- DLX3 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); catalogued as rs756092425, COSV71547409; called by muse, mutect2, varscan2
- DPAGT1 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV62613963; called by muse, mutect2, varscan2
- DST | c.2542C>T p.Q848* (on ENST00000361203 / NM_001374722.1; = p.Q522* on NM_001723.6) | Nonsense Mutation (SNP) | VAF 40/89 reads (45%) | catalogued as COSV99753280; called by muse, mutect2, varscan2
- DUOX2 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs1300558168, COSV50993077; called by muse, mutect2, varscan2
- DYRK1B | c.780C>G p.F260L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59912875; called by muse, mutect2, varscan2
- DZIP1 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.16); PolyPhen benign (0.116); catalogued as rs1322320022, COSV61263940; called by muse, mutect2, varscan2
- EDN2 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV65423338; called by muse, mutect2, varscan2
- EEF1A1 | c.1297G>T p.V433F | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV58548882, COSV58549793; called by muse, mutect2, varscan2
- EGF | c.1918G>A p.D640N | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.046); catalogued as COSV54475664; called by muse, mutect2, varscan2
- EGFLAM | c.2495T>G p.I832R (on ENST00000354891 / NM_001205301.2; = p.I824R on NM_152403.4) | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV59293411; called by muse, mutect2, varscan2
- EGFR | c.1077C>A p.F359L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51771467, COSV51842040; called by muse, mutect2, varscan2
- EIF2AK1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.031); catalogued as COSV52236113; called by muse, mutect2, varscan2
- EIF3F | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.482); catalogued as rs1400554883, COSV59141191; called by muse, mutect2, varscan2
- EIF4EBP2 | c.173T>G p.F58C | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64667180; called by muse, mutect2, varscan2
- EIF4H | c.469+1G>A p.X157_splice | Splice Site (SNP) | VAF 11/72 reads (15%) | catalogued as COSV56081458; called by muse, mutect2, varscan2
- ELF3 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs556702229, COSV62837208; called by muse, mutect2, varscan2
- ELK4 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 33/57 reads (58%) | catalogued as COSV56985767, COSV99222290; called by muse, mutect2, varscan2
- ELP1 | c.1798C>T p.P600S | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.031); catalogued as COSV65896275; called by muse, mutect2, varscan2
- EML2 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV55597505; called by muse, mutect2, varscan2
- EPB41L2 | c.1762C>T p.Q588* | Nonsense Mutation (SNP) | VAF 41/127 reads (32%) | catalogued as COSV100440431; called by muse, mutect2, varscan2
- EPHA8 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs201689882, COSV51268685; called by muse, mutect2
- EPN2 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1268264611, COSV100127474; called by muse, mutect2, varscan2
- EPRS1 | c.2861C>T p.S954L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.219); catalogued as rs144026458; called by muse, mutect2, varscan2
- EPX | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56594901; called by muse, mutect2, varscan2
- ERBIN | c.2017G>A p.D673N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1163354083, COSV52310870; called by muse, mutect2, varscan2
- ERCC2 | c.239T>C p.I80T | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV55538725; called by muse, mutect2, varscan2
- ESYT3 | c.2618C>T p.S873L | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV67440282; called by muse, mutect2, varscan2
- EXOC3 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59265593; called by muse, mutect2, varscan2
- EXOSC5 | c.22G>T p.D8Y | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.172); catalogued as rs1001539566, COSV54195488; called by muse, mutect2
- F2 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); catalogued as rs200969932, COSV61314728, COSV61318280; called by muse, mutect2, varscan2
- FAAP24 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54274928; called by muse, mutect2, varscan2
- FAM110C | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59655666; called by muse, mutect2, varscan2
- FAM227B | c.1253C>T p.T418I | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV54805556; called by muse, mutect2, varscan2
- FANCI | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as rs886051507, COSV55522877; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT3 | c.7330A>C p.M2444L | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV53076232; called by muse, mutect2, varscan2
- FAT4 | c.11761C>T p.P3921S | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV58671775; called by muse, mutect2, varscan2
- FBXW7 | c.1522C>T p.Q508* (on ENST00000281708 / NM_001349798.2; = p.Q428* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 22/78 reads (28%) | catalogued as COSV55912378; called by muse, varscan2
- FCHO1 | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1422951589, COSV53180775; called by muse, mutect2, varscan2
- FCRL4 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs201701822, COSV54859781; called by muse, mutect2, varscan2
- FER1L6 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.88); catalogued as COSV67548155; called by muse, mutect2, varscan2
- FERMT3 | c.1702G>A p.D568N (on ENST00000279227 / NM_178443.3; = p.D564N on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/62 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54172074; called by muse, varscan2
- FILIP1 | c.2746C>A p.P916T | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52722974; called by muse, mutect2, varscan2
- FMN2 | c.4555C>G p.L1519V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60417147; called by muse, mutect2, varscan2
- FMO2 | c.542G>C p.G181A | Missense Mutation (SNP) | VAF 5/130 reads (4%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.894); catalogued as COSV99269018; called by muse, mutect2
- FNIP2 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 77/133 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as COSV52436567; called by muse, mutect2, varscan2
- FRAS1 | c.2323G>A p.D775N | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV53589372; called by muse, mutect2, varscan2
- FRMD6 | c.1307C>G p.S436* (on ENST00000344768 / NM_001267046.2; = p.S428* on NM_152330.4) | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100655629; called by muse, mutect2, varscan2
- FRMPD2 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.391); catalogued as rs146726612, COSV59715231; called by muse, mutect2, varscan2
- GABRA4 | c.1124C>A p.A375D | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.062); catalogued as COSV51922688; called by muse, mutect2, varscan2
- GAS6 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as COSV59847189; called by muse, mutect2, varscan2
- GATA3 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.619); catalogued as rs1414155299, COSV60515573, COSV60517689; called by muse, mutect2, varscan2
- GDF5 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV65499380; called by muse, mutect2, varscan2
- GIMAP8 | c.336A>C p.E112D | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.764); catalogued as COSV56229725; called by muse, mutect2, varscan2
- GOLGA2 | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.13); catalogued as COSV57848916, COSV57855001; called by muse, mutect2, varscan2
- GPR75 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); catalogued as COSV61824786; called by muse, mutect2, varscan2
- GPX3 | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.138); catalogued as COSV59303694; called by muse, mutect2, varscan2
- GRIP2 | c.3211G>A p.D1071N (on ENST00000619221; = p.D974N on NM_001080423.4) | Missense Mutation (SNP) | VAF 73/101 reads (72%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.462); catalogued as COSV56119678, COSV56119768, COSV56125655; called by muse, mutect2, varscan2
- GTF2I | c.748C>G p.Q250E | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV60399230; called by muse, mutect2, varscan2
- GUCY2C | c.1645G>C p.G549R | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367698688, COSV53786584, COSV53786766; called by muse, mutect2, varscan2
- H2BC8 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.09); catalogued as COSV55126191, COSV55126595; called by muse, mutect2, varscan2
- H4C11 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.655); catalogued as COSV100747975; called by muse, mutect2, varscan2
- H4C9 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as rs376974407; called by muse, mutect2, varscan2
- HDAC7 | c.2484G>A p.M828I (on ENST00000427332; = p.M867I on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV99315842; called by muse, mutect2, varscan2
- HDX | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 54/114 reads (47%) | catalogued as COSV99946943; called by muse, mutect2, varscan2
- HERC6 | c.2160C>G p.F720L | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52027677; called by muse, mutect2, varscan2
- HIPK1 | c.2821G>T p.D941Y | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61245967; called by muse, mutect2
- HMCN1 | c.8983G>C p.D2995H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs143661563; called by muse, mutect2, varscan2
- HOMER1 | c.360G>C p.K120N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV56523697; called by muse, mutect2, varscan2
- HTR2B | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV51449028; called by muse, mutect2, varscan2
- HUWE1 | c.3940G>A p.E1314K | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.078); catalogued as COSV53334895; called by muse, mutect2, varscan2
- ICE1 | c.1370C>A p.S457Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as COSV56819235; called by muse, mutect2, varscan2
- IGSF22 | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.741); catalogued as rs1460990278, COSV60030905, COSV60035597; called by muse, mutect2, varscan2
- IL12RB2 | c.2446G>A p.A816T | Missense Mutation (SNP) | VAF 47/290 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143899990; called by muse, mutect2, varscan2
- IL1RL2 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs150558280; called by muse, mutect2, varscan2
- IQCC | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT tolerated (0.44); PolyPhen benign (0.021); catalogued as rs1034340461, COSV52207531; called by muse, mutect2, varscan2
- ISY1 | c.666G>C p.S222= | Splice Region (SNP) | VAF 10/40 reads (25%) | catalogued as COSV56439738; called by muse, mutect2, varscan2
- ITGA8 | c.224T>G p.V75G | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV65224679; called by muse, mutect2
- ITGB7 | c.2044A>G p.I682V | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57237742; called by muse, mutect2
- ITPKB | c.1889A>G p.N630S | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs146855114; called by muse, mutect2, varscan2
- ITPR2 | c.6457C>G p.R2153G | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67264700, COSV67276674; called by muse, mutect2, varscan2
- ITSN1 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.385); catalogued as rs376139396; called by muse, mutect2, varscan2
- KAT7 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52013087; called by muse, mutect2, varscan2
- KCNA7 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1254458839, COSV55502876; called by muse, mutect2, varscan2
- KCNA7 | c.411G>C p.E137D | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs778668555, COSV55502885, COSV55504642; called by muse, mutect2, varscan2
- KIAA0319L | c.1609G>C p.E537Q | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57842054; called by muse, mutect2, varscan2
- KIF13B | c.4211A>G p.N1404S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as rs1380189517, COSV101576033; called by muse, mutect2, varscan2
- KIF21A | c.2497C>G p.L833V (on ENST00000361418 / NM_001378440.1; = p.L820V on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as rs979633626, COSV62767266, COSV62777812; called by muse, mutect2, varscan2
- KIFC2 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV56759922; called by muse, mutect2, varscan2
- KMT2B | c.8092A>T p.S2698C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99495018; called by muse, mutect2
- KMT2C | c.9544G>C p.E3182Q | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51293051; called by muse, mutect2
- LAMA3 | c.4172G>A p.R1391Q | Missense Mutation (SNP) | VAF 110/166 reads (66%) | SIFT tolerated (0.45); PolyPhen benign (0.022); catalogued as rs200732328; called by muse, mutect2, varscan2
- LAMA3 | c.5969G>A p.R1990K (on ENST00000313654 / NM_198129.4; = p.R381K on NM_000227.6) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.02); catalogued as COSV52529778; called by muse, mutect2, varscan2
- LAMA3 | c.8365G>A p.D2789N (on ENST00000313654 / NM_198129.4; = p.D1180N on NM_000227.6) | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52529803; called by muse, varscan2
- LIFR | c.769C>G p.Q257E | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54684624; called by muse, mutect2, varscan2
- LIMS1 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as rs770508766, COSV100185620; called by muse, mutect2, varscan2
- LIMS1 | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.173); catalogued as rs748854260, COSV57539147; called by muse, mutect2, varscan2
- LIPN | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV68383680; called by muse, mutect2, varscan2
- LRRC49 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as rs1208450042, COSV53007931; called by muse, mutect2, varscan2
- LRRCC1 | c.3085C>G p.Q1029E | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV64482596, COSV64483320; called by muse, mutect2, varscan2
- LY75 | c.517T>A p.F173I | Missense Mutation (SNP) | VAF 73/100 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55101973; called by muse, mutect2, varscan2
- MAFB | c.744C>G p.N248K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100965031; called by muse, mutect2, varscan2
- MAGEA12 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 45/53 reads (85%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1488921787, COSV63294179, COSV99057042; called by muse, mutect2, varscan2
- MAN1A2 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV62976246; called by muse, mutect2, varscan2
- MAP10 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV69362741; called by muse, mutect2, varscan2
- MAP4K3 | c.1056T>C p.L352= | Splice Region (SNP) | VAF 23/62 reads (37%) | catalogued as rs1194707515, COSV55709976; called by muse, varscan2
- MBD5 | c.1922G>A p.R641Q | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV68695773; called by muse, mutect2, varscan2
- MCM4 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50621242; called by muse, mutect2, varscan2
- MED13 | c.3556G>A p.D1186N | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.989); catalogued as rs777515608, COSV67261939; called by muse, mutect2, varscan2
- MEIOC | c.755C>A p.T252K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as rs1273526569, COSV63439432, COSV63440192; called by muse, mutect2, varscan2
- METAP1D | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 70/122 reads (57%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as rs950104589, COSV59928925; called by muse, mutect2, varscan2
- METTL24 | c.796C>T p.L266F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58820866; called by muse, mutect2, varscan2
- MFN2 | c.1150C>G p.R384G | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as CM132482, COSV52420429; called by muse, mutect2, varscan2
- MGAT1 | c.1011G>T p.Q337H | Missense Mutation (SNP) | VAF 29/39 reads (74%) | PolyPhen benign (0); catalogued as COSV57133054, COSV57133981; called by muse, mutect2, varscan2
- MICALL1 | c.1859C>T p.S620L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.063); catalogued as rs1229913111, COSV53239283; called by muse, mutect2, varscan2
- MRPL47 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1560021894, COSV52019412, COSV52021783; called by muse, mutect2, varscan2
- MS4A14 | c.353C>G p.S118C | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.691); catalogued as COSV55733098; called by muse, mutect2, varscan2
- MTBP | c.704C>A p.S235* | Nonsense Mutation (SNP) | VAF 32/195 reads (16%) | catalogued as COSV100011950, COSV100012652, COSV59966168; called by muse, mutect2, varscan2
- MTCH2 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs373148624; called by muse, mutect2, varscan2
- MYO1B | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58427097; called by muse, mutect2, varscan2
- MYO5C | c.3583G>A p.E1195K | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated (0.28); PolyPhen benign (0.044); catalogued as COSV55902586; called by muse, mutect2, varscan2
- MYPOP | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1263024233, COSV100447830; called by muse, mutect2, varscan2
- NAA25 | c.1519C>G p.Q507E | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV55702019; called by muse, mutect2, varscan2
- NAF1 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as rs1408584443, COSV56803281; called by muse, mutect2, varscan2
- NCL | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV59544870; called by muse, mutect2, varscan2
- NCOA3 | c.307A>G p.T103A | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.562); catalogued as COSV59065669; called by muse, mutect2, varscan2
- NEK11 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as rs746655708, COSV67279437; called by muse, mutect2, varscan2
- NEK5 | c.509A>T p.Y170F | Missense Mutation (SNP) | VAF 47/57 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62878859; called by muse, mutect2, varscan2
- NINJ1 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs763956891, COSV64922497; called by muse, mutect2, varscan2
- NKTR | c.2821C>A p.L941M | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.191); catalogued as COSV51769382; called by muse, mutect2, varscan2
- NLRC5 | c.5067C>A p.H1689Q | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV52649156; called by muse, varscan2
- NLRP7 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs1377290637, COSV60171043; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOP10 | c.168G>A p.M56I | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV60995059; called by muse, mutect2, varscan2
- NOX1 | c.128G>A p.R43K | Missense Mutation (SNP) | VAF 65/73 reads (89%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as rs781400735, COSV54193332, COSV54195564, COSV99471576; called by muse, mutect2, varscan2
- NPHP3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.881); catalogued as rs1465502034, COSV100446713; called by muse, mutect2, varscan2
- NRIP1 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 74/115 reads (64%) | SIFT tolerated (0.15); PolyPhen benign (0.241); catalogued as rs778412701, COSV59655109; called by muse, mutect2, varscan2
- NTM | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100867981; called by muse, mutect2, varscan2
- NUP205 | c.3205C>T p.Q1069* | Nonsense Mutation (SNP) | VAF 11/81 reads (14%) | catalogued as COSV99606682; called by muse, mutect2, varscan2
- NUP37 | c.289A>T p.T97S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs1265851856, COSV51837092; called by muse, mutect2, varscan2
- OAS2 | c.2111C>T p.S704L | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs895811975, COSV60801131; called by muse, mutect2, varscan2
- OBSL1 | c.1097A>G p.N366S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.264); catalogued as rs1333990991, COSV54712843; called by muse, mutect2, varscan2
- OR51A7 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as rs753338342, COSV63788015; called by muse, mutect2, varscan2
- OR8J3 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56879417; called by muse, mutect2, varscan2
- OS9 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.068); catalogued as COSV57781964; called by muse, mutect2, varscan2
- OSBP2 | c.1623G>A p.P541= | Splice Region (SNP) | VAF 26/74 reads (35%) | catalogued as rs781758349, COSV60239700; called by muse, mutect2, varscan2
- OSMR | c.2045-1G>C p.X682_splice | Splice Site (SNP) | VAF 14/55 reads (25%) | catalogued as COSV57081052, COSV57093069; called by muse, mutect2, varscan2
- OVCH1 | c.2648G>A p.S883N | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV58959597; called by muse, mutect2
- OXR1 | c.948C>G p.I316M (on ENST00000442977 / NM_001198532.1; = p.I315M on NM_018002.3) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV56324364; called by muse, mutect2
- PALD1 | c.748A>G p.T250A | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as COSV54970765; called by muse, mutect2, varscan2
- PAPPA | c.3940T>C p.C1314R | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60277533; called by muse, mutect2, varscan2
- PCBP1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV57849765; called by muse, mutect2, varscan2
- PCDHB14 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53386520; called by muse, mutect2
- PCDHB8 | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 129/276 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.732); catalogued as rs782295515, COSV50754176; called by muse, mutect2, varscan2
- PCDHGB6 | c.1330G>C p.D444H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53899352; called by muse, mutect2, varscan2
- PCF11 | c.1693C>G p.R565G | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53527557, COSV53532343; called by muse, mutect2, varscan2
- PCSK6 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59338321; called by muse, mutect2, varscan2
- PCSK7 | c.566G>C p.G189A | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs932709890, COSV58005815; called by muse, mutect2, varscan2
- PDE1C | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.11); catalogued as COSV58503628; called by muse, mutect2, varscan2
- PDIK1L | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV65322330; called by muse, mutect2
- PGD | c.1192G>C p.A398P | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs757401268, COSV54620294; called by muse, mutect2, varscan2
- PHF21A | c.982C>T p.L328F (on ENST00000418153 / NM_001101802.3; = p.L329F on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as COSV57649268; called by muse, mutect2, varscan2
- PIK3C2B | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs747728370, COSV100915982; called by muse, varscan2
- PIK3CD | c.2337G>C p.K779N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100740060; called by muse, mutect2
- PKD1L2 | c.785A>C p.E262A | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.194); catalogued as COSV61411720; called by muse, mutect2, varscan2
- PLB1 | c.1695C>G p.Y565* | Nonsense Mutation (SNP) | VAF 16/24 reads (67%) | catalogued as rs1204236067, COSV100214968; called by muse, mutect2, varscan2
- PLD1 | c.815T>C p.I272T | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1227492747, COSV60565361; called by muse, mutect2, varscan2
- PLEKHO2 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1321665799, COSV60261529, COSV60262962; called by muse, mutect2, varscan2
- PLXNA2 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs779666190, COSV65437661, COSV65441594; called by muse, mutect2, varscan2
- PNMA8B | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0.137); catalogued as COSV66535751; called by muse, mutect2, varscan2
- POLE | c.3367G>C p.D1123H | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1565953965, COSV100268687, COSV57674298; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRR16 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as rs756035915, COSV101086691; called by muse, varscan2
- PRRC2C | c.3272C>T p.S1091L (on ENST00000367742; = p.S1089L on NM_015172.4) | Missense Mutation (SNP) | VAF 60/96 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV58901004; called by muse, mutect2, varscan2
- PSIP1 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 46/57 reads (81%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV66253632; called by muse, mutect2, varscan2
- PTPRB | c.5615G>C p.G1872A | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99716542; called by muse, mutect2
- RAB3GAP2 | c.3507G>A p.M1169I | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as rs1484216760, COSV62782183; called by muse, mutect2, varscan2
- RARS1 | c.280G>C p.D94H | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV51561997; called by muse, mutect2, varscan2
- RBM24 | c.592C>T p.Q198* (on ENST00000379052 / NM_001143942.2; = p.Q153* on NM_153020.2) | Nonsense Mutation (SNP) | VAF 16/29 reads (55%) | catalogued as rs755149444, COSV100552904; called by muse, mutect2, varscan2
- RELCH | c.3442C>G p.L1148V | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as COSV56882201, COSV56888049; called by muse, mutect2, varscan2
- RELN | c.8522C>T p.S2841L | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV58986088; called by muse, mutect2, varscan2
- RFC4 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV56215517, COSV56217980; called by muse, mutect2, varscan2
- RNF216 | c.68-1G>C p.X23_splice | Splice Site (SNP) | VAF 12/54 reads (22%) | catalogued as COSV66289078; called by muse, mutect2, varscan2
- RO60 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as COSV66473169; called by muse, mutect2, varscan2
- RPS6KA3 | c.1267G>T p.E423* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV101084240; called by muse, mutect2
- RRP12 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as rs577455394, COSV59664801; called by muse, mutect2, varscan2
- RRP15 | c.23C>G p.S8* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100860712; called by muse, mutect2, varscan2
- SACS | c.5785C>T p.R1929W | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs141019064, COSV66534324; called by muse, mutect2, varscan2
- SARAF | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.5); catalogued as COSV56356821; called by muse, mutect2, varscan2
- SAYSD1 | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57722810; called by muse, mutect2, varscan2
- SBNO1 | c.79G>C p.D27H | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV57338923; called by muse, mutect2, varscan2
- SCAF11 | c.2192C>G p.S731C | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.87); catalogued as rs776453624, COSV65474839; called by muse, mutect2, varscan2
- SEPTIN12 | c.399C>G p.I133M | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760512752, COSV51615518; called by muse, mutect2, varscan2
- SF3A1 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53167230; called by muse, varscan2
- SF3B2 | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV59426970; called by muse, mutect2, varscan2
- SHOC2 | c.136A>T p.K46* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99510016; called by muse, mutect2, varscan2
- SHROOM2 | c.4705G>A p.E1569K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV101098368; called by muse, mutect2, varscan2
- SIM1 | c.1768G>C p.D590H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.482); catalogued as rs1377252112, COSV99492158; called by muse, mutect2
- SKOR1 | c.2876T>G p.F959C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58243896; called by muse, mutect2, varscan2
- SLC12A6 | c.620G>A p.R207H (on ENST00000354181 / NM_001365088.1; = p.R156H on NM_005135.2) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555381416, COSV51622808; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC16A5 | c.382G>A p.V128M | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.572); catalogued as COSV61675318; called by muse, mutect2, varscan2
- SLC22A12 | c.70C>G p.L24V | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV60570850; called by muse, varscan2
- SLC29A2 | c.1146G>C p.Q382H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV60802812; called by muse, mutect2, varscan2
- SLC2A2 | c.1537G>A p.V513I | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV58584548; called by muse, mutect2, varscan2
- SLC38A2 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56744034; called by muse, mutect2, varscan2
- SLC39A12 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1319922649, COSV66195070; called by muse, mutect2, varscan2
- SLC9C2 | c.15C>A p.F5L | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV62943824; called by muse, mutect2
- SLIT2 | c.2447T>A p.I816N | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56560305; called by muse, mutect2, varscan2
- SLITRK5 | c.2303G>A p.R768Q | Missense Mutation (SNP) | VAF 46/58 reads (79%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as rs1377185185, COSV61521019; called by muse, varscan2
- SMARCA2 | c.1394A>G p.Y465C | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV61804792; called by muse, mutect2, varscan2
- SOS1 | c.1663G>C p.D555H | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67673817; called by muse, mutect2, varscan2
- SPAG17 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 130/207 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV60452889; called by muse, mutect2, varscan2
- SPTBN5 | c.3304C>T p.Q1102* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as rs775518103, COSV100311033; called by mutect2, varscan2
- SPTY2D1 | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV60472836; called by muse, varscan2
- SPTY2D1 | c.719C>G p.T240R | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as COSV60472846; called by muse, varscan2
- SPTY2D1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV60472854; called by muse, varscan2
- SRGAP3 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV64530528; called by muse, mutect2, varscan2
- ST14 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333246624, COSV53831383; called by muse, mutect2, varscan2
- STEAP2 | c.33G>C p.K11N | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV55289129; called by muse, mutect2
- STUM | c.366C>G p.D122E | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV64683439; called by muse, mutect2, varscan2
- SYCP3 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.796); catalogued as COSV57148242; called by muse, mutect2, varscan2
- SYNE1 | c.9685C>T p.Q3229* (on ENST00000367255 / NM_182961.4; = p.Q3236* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 19/77 reads (25%) | catalogued as COSV99557951; called by muse, mutect2, varscan2
- SYT11 | c.9G>C p.E3D | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.012); catalogued as COSV55186847; called by muse, mutect2, varscan2
- TADA3 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs760342366, COSV100112951; called by muse, mutect2
- TBC1D19 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV53514324; called by muse, mutect2, varscan2
- TCF19 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV52562870; called by muse, mutect2, varscan2
- TCHH | c.5602G>A p.E1868K | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.875); catalogued as rs1354283536, COSV64272912; called by muse, mutect2, varscan2
- TCN2 | c.10C>A p.L4I | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.681); catalogued as COSV53190664; called by muse, mutect2, varscan2
- TESC | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV58810901; called by muse, mutect2, varscan2
- TMEM267 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV67992383, COSV67992959; called by muse, mutect2, varscan2
- TMIGD1 | c.297C>G p.I99M | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV61027966, COSV61028584; called by muse, mutect2, varscan2
- TNFRSF10B | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs775489972, COSV52391099; called by muse, mutect2, varscan2
- TNFRSF13C | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as rs776189874, COSV52169225, COSV99351674, COSV99351810; called by muse, mutect2, varscan2
- TNFRSF17 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50000035; called by muse, mutect2, varscan2
- TOPBP1 | c.2080C>T p.H694Y | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1203806604, COSV53432428; called by muse, mutect2, varscan2
- TP63 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV53196531; called by muse, mutect2, varscan2
- TRAPPC11 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs1011666044, COSV58214569; called by muse, mutect2, varscan2
- TRIM38 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as rs1266712951, COSV62641678; called by muse, mutect2, varscan2
- TRMO | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 42/48 reads (88%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV64291333; called by muse, mutect2, varscan2
- TRRAP | c.7808G>A p.R2603Q (on ENST00000359863 / NM_001244580.1; = p.R2585Q on NM_003496.3) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.16); catalogued as rs1486799590, COSV62839004; called by muse, mutect2, varscan2
- TSGA10IP | c.1655C>G p.P552R | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.78); catalogued as COSV100408943, COSV100409085; called by muse, mutect2, varscan2
- TSSK6 | c.60G>C p.E20D | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV53062576; called by muse, mutect2, varscan2
- TTN | c.49111G>A p.D16371N (on ENST00000591111; = p.D8947N on NM_003319.4) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | PolyPhen benign (0.001); catalogued as COSV59890599; called by muse, mutect2
- TTN | c.17239G>A p.D5747N (on ENST00000591111; = p.D4820N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | PolyPhen benign (0.005); catalogued as COSV59890637; called by muse, mutect2, varscan2
- TUT1 | c.1780C>T p.L594F | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV53468762; called by muse, mutect2, varscan2
- UBXN4 | c.265C>G p.P89A | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV55633441; called by muse, mutect2, varscan2
- UNC13A | c.3513C>A p.D1171E | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53188471; called by muse, mutect2, varscan2
- USP33 | c.2702C>T p.T901I | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.771); catalogued as COSV62468267; called by muse, mutect2
- USP40 | c.2834C>T p.S945L | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs754906656, COSV52477286; called by muse, mutect2, varscan2
- UTRN | c.10121C>T p.S3374F | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.594); catalogued as COSV62307347; called by muse, mutect2, varscan2
- VAV3 | c.1519G>C p.D507H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV100579836, COSV58377115; called by muse, mutect2
- WASHC5 | c.1507C>A p.Q503K | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); catalogued as rs1469001345, COSV59194092; called by muse, mutect2, varscan2
- WFS1 | c.1961C>T p.S654L | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1189512943, COSV56987430; called by muse, mutect2, varscan2
- WNT10B | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.232); catalogued as rs553395822, COSV56404840; called by muse, mutect2, varscan2
- XIRP1 | c.5077G>A p.D1693N | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV61136916; called by muse, mutect2, varscan2
- YARS2 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as rs748941040, COSV61401342, COSV61402145; called by muse, mutect2, varscan2
- YTHDC2 | c.4123C>G p.R1375G | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.658); catalogued as rs762256508, COSV50736654, COSV50746096; called by muse, mutect2, varscan2
- YWHAZ | c.701G>C p.G234A | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV62053429; called by muse, mutect2, varscan2
- ZBTB22 | c.1455C>G p.I485M | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as COSV56466650; called by muse, mutect2, varscan2
- ZBTB40 | c.1532C>T p.S511L | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV65144635; called by muse, mutect2, varscan2
- ZEB2 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 66/122 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs905118258, COSV57951518; called by muse, mutect2, varscan2
- ZIK1 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs1262630233, COSV56736465, COSV56737642; called by muse, mutect2, varscan2
- ZKSCAN5 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as rs759875739, COSV58741841; called by muse, mutect2, varscan2
- ZKSCAN7 | c.399G>C p.Q133H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV56271726; called by muse, mutect2, varscan2
- ZNF517 | c.732G>C p.Q244H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as rs1307416391, COSV100743540; called by muse, mutect2, varscan2
- ZNF563 | c.548A>T p.N183I | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV53369609; called by muse, mutect2, varscan2
- ZNF595 | c.1252C>T p.H418Y | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs782677217, COSV59547275; called by muse, mutect2, varscan2
- ZNF620 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs771330146, COSV100094023; called by muse, mutect2
- ZNF628 | c.2491A>G p.T831A | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1305601741, COSV52697924; called by muse, mutect2, varscan2
- ZNF785 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs552503849, COSV67876160; called by muse, mutect2, varscan2
- ZNF808 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 40/185 reads (22%) | catalogued as rs757299336, COSV100707852; called by muse, mutect2, varscan2
- ZNF808 | c.1312C>G p.Q438E | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.36); catalogued as COSV63118646; called by muse, mutect2, varscan2
- ZNF81 | c.1336C>G p.Q446E | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58574896; called by muse, mutect2, varscan2
- ZNFX1 | c.3221G>A p.R1074H | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65579948; called by muse, mutect2
- ZNRF3 | c.2048C>T p.S683L (on ENST00000544604 / NM_001206998.2; = p.S583L on NM_032173.3) | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.704); catalogued as COSV60431333; called by muse, mutect2, varscan2
- ZPR1 | c.1195A>T p.M399L | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs973483931, COSV57062236; called by muse, mutect2, varscan2
- ZYG11B | c.279C>G p.I93M | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV53750028; called by muse, mutect2, varscan2
- ZYG11B | c.770G>C p.R257P | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as COSV53750046; called by muse, mutect2, varscan2
- AL391650.1 | c.*34-5_*41del | Splice Site (DEL) | VAF 24/88 reads (27%) | called by mutect2, pindel, varscan2
- CARMIL2 | c.2322dup p.I775Hfs*4 | Frame Shift Ins (INS) | VAF 8/31 reads (26%) | called by mutect2, pindel, varscan2
- DHRS4 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHV4-61 | c.58C>G p.Q20E | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- MEFV | c.103_105del p.K35del | In Frame Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- MYO1F | c.402_414+11del p.X134_splice | Splice Site (DEL) | VAF 28/73 reads (38%) | called by mutect2, pindel, varscan2
- PLEKHN1 | c.254_255dup p.R86Gfs*6 | Frame Shift Ins (INS) | VAF 14/53 reads (26%) | called by mutect2, pindel, varscan2
- RAB11FIP5 | c.1232_1256del p.K411Tfs*22 | Frame Shift Del (DEL) | VAF 27/106 reads (25%) | called by mutect2, pindel
- SEMA3F | c.1597_1622del p.Y533Tfs*16 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | called by mutect2, pindel
- TENM3 | c.6193_6195del p.D2065del | In Frame Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- TRBV4-1 | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- A2ML1 | c.627C>T p.F209= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV55285732; called by muse, mutect2, varscan2
- ACACA | c.4656C>T p.I1552= | Silent (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- ACOX1 | c.123G>A p.L41= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV53131340; called by muse, mutect2, varscan2
- ADAMTS18 | c.462C>T p.S154= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV51398847; called by muse, mutect2, varscan2
- ADCK2 | c.405G>A p.L135= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as COSV50780730; called by muse, mutect2, varscan2
- AIFM1 | c.457C>A p.R153= | Silent (SNP) | VAF 66/73 reads (90%) | catalogued as COSV54852558, COSV54854675; called by muse, mutect2, varscan2
- AIM2 | c.234A>G p.A78= | Silent (SNP) | VAF 16/144 reads (11%) | catalogued as COSV63698229; called by muse, mutect2, varscan2
- ALMS1 | c.11448G>A p.Q3816= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV52502873; called by muse, mutect2, varscan2
- ALPK3 | c.3075G>A p.Q1025= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV51929440, COSV99360675, COSV99361152; called by muse, mutect2
- AMBP | c.12C>T p.L4= | Silent (SNP) | VAF 37/42 reads (88%) | catalogued as rs373102429, COSV54322321; called by muse, mutect2, varscan2
- ANK3 | c.183A>T p.I61= | Silent (SNP) | VAF 80/142 reads (56%) | catalogued as COSV55044458; called by muse, mutect2, varscan2
- ANKMY1 | c.1488G>A p.L496= | Silent (SNP) | VAF 56/66 reads (85%) | catalogued as COSV56030171; called by muse, mutect2, varscan2
- ANKS1B | c.3213G>C p.L1071= (on ENST00000547776 / NM_152788.4; = p.L237= on NM_020140.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV59115171; called by muse, mutect2
- ARHGEF10L | c.2142C>G p.L714= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV51427997; called by muse, mutect2, varscan2
- ARHGEF10L | c.2334C>T p.F778= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs751278456, COSV51428031, COSV51430695; called by muse, mutect2, varscan2
- ATP7A | c.2688G>A p.Q896= | Silent (SNP) | VAF 80/91 reads (88%) | catalogued as COSV58442798; called by muse, mutect2, varscan2
- B3GALNT1 | c.810C>T p.V270= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs779326139, COSV57579640; called by muse, mutect2, varscan2
- B3GNT3 | c.927G>T p.L309= | Silent (SNP) | VAF 35/124 reads (28%) | catalogued as rs1434283461, COSV57952773; called by muse, mutect2, varscan2
- BCAR3 | c.1269C>T p.L423= | Silent (SNP) | VAF 29/46 reads (63%) | catalogued as COSV53071908; called by muse, mutect2, varscan2
- BLVRB | c.27C>T p.F9= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs766498637, COSV54568731; called by muse, mutect2, varscan2
- BOP1 | c.681C>T p.F227= | Silent (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- BPTF | c.5253C>T p.V1751= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs1399169850, COSV58831450; called by muse, mutect2, varscan2
- BRINP3 | c.1077G>A p.E359= | Silent (SNP) | VAF 24/225 reads (11%) | catalogued as rs1052843669, COSV66513651; called by muse, mutect2, varscan2
- BUB1B | c.2662C>T p.L888= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV55009918; called by mutect2, varscan2
- C1QTNF9 | c.585G>A p.E195= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100129842; called by muse, mutect2, varscan2
- C1orf100 | c.159C>A p.L53= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs1318441537, COSV57371936; called by muse, varscan2
- CACNB1 | c.474C>T p.F158= | Silent (SNP) | VAF 43/105 reads (41%) | catalogued as COSV59998032; called by muse, mutect2, varscan2
- CCDC158 | c.2883G>A p.S961= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as rs376345467; called by muse, mutect2, varscan2
- CD1B | c.162G>A p.Q54= | Silent (SNP) | VAF 45/203 reads (22%) | catalogued as COSV63803786; called by muse, mutect2, varscan2
- CEP170B | c.4512G>A p.Q1504= (on ENST00000453495; = p.Q1433= on NM_015005.3) | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as COSV99229722; called by muse, mutect2, varscan2
- CFAP74 | c.996C>T p.F332= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV54564643; called by muse, mutect2, varscan2
- CHD5 | c.1368C>T p.L456= | Silent (SNP) | VAF 47/92 reads (51%) | catalogued as COSV52407658; called by muse, mutect2, varscan2
- CLDN14 | c.606G>A p.T202= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs763313658, COSV59771674; called by muse, mutect2, varscan2
- CP | c.57G>A p.A19= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs775969249, COSV52829053; called by muse, mutect2, varscan2
- CRB1 | c.591C>T p.N197= | Silent (SNP) | VAF 10/101 reads (10%) | catalogued as rs770973303, COSV66336357; ClinVar: likely benign; called by muse, mutect2, varscan2
- CREB3L4 | c.1014G>A p.L338= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV55131375; called by muse, mutect2, varscan2
- CSTF2T | c.159G>A p.T53= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV58655872, COSV58655972; called by muse, mutect2, varscan2
- CTNND2 | c.2268C>T p.I756= | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as rs767036575, COSV58864248, COSV58899357; called by muse, mutect2, varscan2
- DDX24 | c.1722G>A p.E574= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs1365145317; called by muse, mutect2
- DENND4B | c.306C>T p.L102= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs749089049, COSV57841064; called by muse, mutect2, varscan2
- DEPTOR | c.24C>T p.G8= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs753189751, COSV53812640; called by muse, mutect2, varscan2
- DKK1 | c.225G>A p.Q75= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs767012063, COSV64759968; called by muse, mutect2, varscan2
- DLGAP4 | c.2157G>A p.Q719= (on ENST00000339266 / NM_001365621.1; = p.Q716= on NM_014902.6) | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV59414464; called by muse, mutect2, varscan2
- DLX1 | c.363C>T p.F121= | Silent (SNP) | VAF 70/111 reads (63%) | catalogued as COSV59393962; called by muse, mutect2, varscan2
- DNAH3 | c.5235C>T p.I1745= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs751933587, COSV54503499; called by muse, mutect2, varscan2
- DNMT3A | c.159G>A p.R53= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs1240408625, COSV53038650; called by muse, mutect2, varscan2
- DTX3L | c.183G>A p.R61= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV56143239; called by muse, mutect2, varscan2
- E2F8 | c.756A>G p.E252= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV51461866; called by muse, mutect2, varscan2
- EIF2AK4 | c.1725C>T p.F575= | Silent (SNP) | VAF 64/133 reads (48%) | catalogued as COSV55465006; called by muse, mutect2, varscan2
- ENTHD1 | c.936C>G p.L312= | Silent (SNP) | VAF 25/110 reads (23%) | catalogued as COSV57317319, COSV57320139; called by muse, mutect2, varscan2
- EPHA10 | c.2469C>T p.F823= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV57621366; called by muse, mutect2, varscan2
- EPS8 | c.453G>A p.L151= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs745417768, COSV55527618; called by muse, mutect2, varscan2
- ERMARD | c.880T>C p.L294= | Silent (SNP) | VAF 49/126 reads (39%) | catalogued as COSV64647578; called by muse, mutect2, varscan2
- EXOC2 | c.2277C>G p.L759= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV57861180; called by muse, mutect2, varscan2
- FANCI | c.660C>G p.L220= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV55522895, COSV55526978; called by muse, mutect2, varscan2
- FANK1 | c.345C>T p.H115= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs753777352, COSV64156162; called by muse, mutect2, varscan2
- FERMT3 | c.1761C>T p.D587= (on ENST00000279227 / NM_178443.3; = p.D583= on NM_031471.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs112045200, COSV54172078; called by muse, varscan2
- FIZ1 | c.1371C>G p.L457= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99684513; called by muse, mutect2
- FLNA | c.4095C>T p.I1365= | Silent (SNP) | VAF 53/139 reads (38%) | catalogued as COSV61037584; called by muse, mutect2, varscan2
- FOXF2 | c.519C>T p.Y173= | Silent (SNP) | VAF 44/112 reads (39%) | catalogued as rs1319068876, COSV52525059, COSV99453232; called by muse, mutect2, varscan2
- FOXRED1 | c.714C>T p.F238= | Silent (SNP) | VAF 49/133 reads (37%) | catalogued as COSV55005171; called by muse, mutect2, varscan2
- GALNT2 | c.459C>T p.L153= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs1481191213; called by muse, mutect2
- GFOD1 | c.396G>A p.K132= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV64954272; called by muse, mutect2, varscan2
- GLI4 | c.816C>T p.C272= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs201405002, COSV60681416; called by muse, mutect2
- GTF3C5 | c.54G>C p.L18= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV100565316; called by muse, mutect2
- HDAC7 | c.516G>A p.R172= (on ENST00000427332; = p.R211= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as rs1309965884, COSV50319546; called by muse, mutect2, varscan2
- HELLS | c.111T>C p.L37= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV53294448; called by muse, mutect2, varscan2
- HPSE2 | c.261C>T p.I87= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as COSV65180604; called by muse, mutect2, varscan2
- HSCB | c.372G>A p.V124= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs767703096, COSV53261919; called by muse, mutect2, varscan2
- IFT81 | c.1311A>G p.Q437= | Silent (SNP) | VAF 26/40 reads (65%) | catalogued as COSV54360542; called by muse, mutect2, varscan2
- INO80 | c.3549C>T p.I1183= | Silent (SNP) | VAF 32/50 reads (64%) | catalogued as COSV62736131; called by muse, mutect2, varscan2
- ITPR3 | c.2049G>T p.L683= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV65405738; called by muse, mutect2, varscan2
- ITPRIPL2 | c.258C>G p.A86= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV67347321; called by muse, mutect2, varscan2
- JCAD | c.552C>A p.V184= | Silent (SNP) | VAF 48/164 reads (29%) | catalogued as COSV64757979; called by muse, mutect2, varscan2
- KBTBD13 | c.1248C>T p.I416= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1291680168, COSV71351336; called by muse, mutect2, varscan2
- KCNC3 | c.621C>T p.P207= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs1054419172, COSV100979208; called by muse, varscan2
- KNDC1 | c.3576G>C p.L1192= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV58831101; called by muse, varscan2
- KRT20 | c.912C>T p.L304= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as rs758767976, COSV51423961; called by muse, mutect2, varscan2
- KRT76 | c.1464G>T p.L488= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as COSV60119148; called by muse, mutect2
- LAMA1 | c.4186C>T p.L1396= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV67532157; called by muse, mutect2, varscan2
- LAMA4 | c.2583G>C p.L861= (on ENST00000230538 / NM_001105206.3; = p.L854= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as COSV57892058; called by muse, mutect2, varscan2
- LGR5 | c.300C>T p.N100= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs545965224, COSV57002288; called by muse, mutect2, varscan2
- LHX4 | c.24C>T p.P8= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as COSV55372967; called by muse, mutect2, varscan2
- LRRK2 | c.5850C>T p.A1950= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as COSV54144122; called by muse, mutect2
- MAP3K10 | c.1539G>A p.L513= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV53420452; called by muse, mutect2, varscan2
- MED13L | c.1824C>T p.L608= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs1189690834, COSV56115818, COSV56130561; called by muse, mutect2, varscan2
- MET | c.1158C>T p.L386= | Silent (SNP) | VAF 59/119 reads (50%) | catalogued as rs1554379184, COSV59256925; ClinVar: likely benign; called by muse, mutect2, varscan2
- MFF | c.585G>C p.P195= | Silent (SNP) | VAF 57/112 reads (51%) | catalogued as rs367621130; called by muse, mutect2, varscan2
- MGAM | c.2310G>C p.L770= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV101527427, COSV72074119; called by muse, mutect2, varscan2
- MPI | c.580C>T p.L194= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs1478515729, COSV60396325; called by muse, mutect2, varscan2
- MPZL3 | c.651G>A p.A217= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs764710610, COSV54052594; called by muse, mutect2, varscan2
- MUC20 | c.1884C>T p.I628= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV57847218; called by muse, mutect2, varscan2
- NAV3 | c.972T>G p.P324= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV57062182; called by muse, mutect2, varscan2
- NCK2 | c.1119C>G p.L373= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV51888488; called by muse, mutect2, varscan2
- NPAS2 | c.1602C>T p.L534= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV59555404; called by muse, mutect2, varscan2
- NPHS2 | c.1041G>A p.L347= | Silent (SNP) | VAF 102/142 reads (72%) | catalogued as COSV62634585; called by muse, mutect2, varscan2
- NSMCE2 | c.513T>A p.I171= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV54894066; called by muse, mutect2, varscan2
- OGDH | c.2031C>T p.D677= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs781776901, COSV56045571; called by muse, mutect2, varscan2
- OGDHL | c.855C>T p.S285= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs774693788, COSV65100776; called by muse, mutect2, varscan2
- OLFM3 | c.105G>A p.T35= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs981906963, COSV100129116; called by muse, mutect2, varscan2
- OR2C1 | c.198C>G p.L66= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV59239619; called by muse, mutect2, varscan2
- OR5AK2 | c.621G>A p.L207= | Silent (SNP) | VAF 35/127 reads (28%) | catalogued as COSV58803808; called by muse, mutect2, varscan2
- PADI1 | c.822G>T p.P274= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as COSV64937758; called by muse, mutect2, varscan2
- PDE3A | c.825G>A p.L275= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as rs750288734, COSV62967221; called by muse, mutect2, varscan2
- PDPR | c.285G>A p.L95= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as COSV99847996; called by muse, mutect2, varscan2
- PDRG1 | c.132G>A p.L44= | Silent (SNP) | VAF 29/120 reads (24%) | catalogued as COSV52430986, COSV52431920; called by muse, mutect2, varscan2
- PLCG1 | c.2775G>A p.K925= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs149943087; called by muse, mutect2, varscan2
- PODXL | c.1195C>T p.L399= (on ENST00000378555 / NM_001018111.3; = p.L367= on NM_005397.4) | Silent (SNP) | VAF 20/148 reads (14%) | catalogued as COSV59868504; called by muse, mutect2, varscan2
- POLM | c.1077C>T p.L359= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV54241418; called by muse, mutect2, varscan2
- PRKACA | c.456C>G p.V152= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV58066667; called by muse, mutect2, varscan2
- PROM1 | c.1227C>T p.F409= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV71699124; called by muse, mutect2, varscan2
- PTGER3 | c.765C>G p.A255= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV60687707; called by muse, mutect2, varscan2
- PTPRG | c.39C>T p.F13= | Silent (SNP) | VAF 85/138 reads (62%) | catalogued as COSV55628822; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1821G>A p.E607= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1290106861, COSV99240059; called by muse, mutect2
- RAB27A | c.30C>T p.I10= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV61014737; called by muse, mutect2, varscan2
- RARG | c.954C>T p.L318= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV58432486; called by muse, mutect2
- RASSF1 | c.900C>T p.F300= (on ENST00000357043 / NM_170714.2; = p.F296= on NM_007182.5) | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV51700049; called by muse, mutect2, varscan2
- RBP4 | c.99C>T p.F33= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV65159601; called by muse, mutect2, varscan2
- SAMD9 | c.2715G>A p.L905= | Silent (SNP) | VAF 4/65 reads (6%) | catalogued as rs919288120, COSV66078158; called by muse, mutect2
- SCAMP3 | c.891G>A p.L297= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV56943733; called by muse, mutect2, varscan2
- SCMH1 | c.1753C>T p.L585= (on ENST00000326197 / NM_001031694.2; = p.L516= on NM_012236.4) | Silent (SNP) | VAF 52/78 reads (67%) | catalogued as COSV58232372; called by muse, mutect2, varscan2
- SCP2 | c.1479T>G p.A493= | Silent (SNP) | VAF 49/85 reads (58%) | catalogued as COSV65260410; called by muse, mutect2, varscan2
- SEMG1 | c.987G>A p.Q329= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs768778177, COSV54871793; called by muse, mutect2, varscan2
- SERPINA11 | c.681G>A p.Q227= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as COSV58241154; called by muse, mutect2, varscan2
- SH3BP2 | c.903C>T p.A301= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV62553547; called by muse, mutect2, varscan2
- SLC19A1 | c.1014C>T p.L338= | Silent (SNP) | VAF 23/35 reads (66%) | catalogued as rs1310408328, COSV60753018; called by muse, mutect2, varscan2
- SPAG4 | c.1236C>T p.F412= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as COSV65329985; called by muse, mutect2, varscan2
- SPATA21 | c.522G>C p.L174= | Silent (SNP) | VAF 16/20 reads (80%) | catalogued as rs746180168, COSV100131109, COSV59185214; called by muse, varscan2
- STXBP5 | c.78G>A p.Q26= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs1183156070, COSV99469709; called by muse, mutect2, varscan2
- TACC2 | c.3759G>A p.V1253= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as rs759701337, COSV57746261; called by muse, mutect2, varscan2
- TAZ | c.162C>T p.I54= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV50010073; called by muse, mutect2
- TBL1XR1 | c.1290C>T p.D430= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs1311275691, COSV70499732; called by muse, mutect2, varscan2
- TIMM21 | c.123G>A p.L41= | Silent (SNP) | VAF 221/429 reads (52%) | catalogued as COSV50053379; called by muse, mutect2, varscan2
- TMEM150A | c.798G>A p.E266= (on ENST00000334462 / NM_001031738.3; = p.E213= on NM_153342.3) | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV57817460; called by muse, mutect2, varscan2
- TMEM203 | c.150C>T p.F50= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as COSV58806280; called by muse, mutect2, varscan2
- TMEM205 | c.168C>T p.F56= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV61514482; called by muse, mutect2, varscan2
- TNKS1BP1 | c.18C>T p.L6= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs553347344, COSV53478240; called by muse, mutect2, varscan2
- TNN | c.2025G>A p.L675= | Silent (SNP) | VAF 83/118 reads (70%) | catalogued as COSV53421686; called by muse, mutect2, varscan2
- TOMM34 | c.861C>G p.L287= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV53838750; called by muse, mutect2, varscan2
- TPM4 | c.33G>A p.L11= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs982601159, COSV61208575; called by muse, mutect2, varscan2
- TRBV6-1 | c.285C>T p.L95= | Silent (SNP) | VAF 70/148 reads (47%) | called by muse, mutect2, varscan2
- TSR3 | c.405G>A p.G135= | Silent (SNP) | VAF 28/38 reads (74%) | catalogued as rs773425228, COSV50103542; called by muse, mutect2, varscan2
- TTC23L | c.789G>A p.Q263= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV72205907, COSV72205981; called by muse, mutect2, varscan2
- TUBGCP6 | c.2556G>A p.S852= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs779813098, COSV50536659; called by muse, mutect2, varscan2
- TYRO3 | c.303C>T p.F101= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as rs760982988; called by muse, mutect2, varscan2
- UQCRFS1 | c.384T>C p.A128= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as rs1311229177, COSV100508054, COSV59184920; called by muse, mutect2
- USH2A | c.7143G>A p.L2381= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as COSV56328223; called by muse, mutect2, varscan2
- UTRN | c.7851G>C p.L2617= | Silent (SNP) | VAF 47/136 reads (35%) | catalogued as COSV62307338; called by muse, mutect2, varscan2
- WDR46 | c.105G>A p.P35= | Silent (SNP) | VAF 42/93 reads (45%) | catalogued as COSV65841939; called by muse, mutect2, varscan2
- ZFP37 | c.30G>A p.L10= | Silent (SNP) | VAF 42/52 reads (81%) | catalogued as COSV65285866; called by muse, mutect2, varscan2
- ZFPM2 | c.1248C>T p.T416= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV65872565; called by muse, mutect2, varscan2
- ZFYVE9 | c.1926C>T p.V642= | Silent (SNP) | VAF 48/113 reads (42%) | catalogued as rs146046897, COSV55090111; called by muse, mutect2, varscan2
- ZNF23 | c.1035C>T p.F345= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV61840475; called by muse, mutect2, varscan2
- ZNF235 | c.984C>T p.F328= | Silent (SNP) | VAF 55/129 reads (43%) | catalogued as COSV52155112, COSV52156919; called by muse, mutect2, varscan2
- ZNF250 | c.1212C>T p.F404= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1374587053, COSV52967951; called by muse, mutect2, varscan2
- ZNF423 | c.1620C>G p.L540= (on ENST00000563137 / NM_001379286.1; = p.L532= on NM_015069.4) | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV52177412; called by muse, mutect2, varscan2
- ZNF644 | c.1596C>T p.F532= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as rs746769810, COSV61346010; called by muse, mutect2, varscan2
- ZSCAN20 | c.1203C>T p.F401= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV63681579; called by muse, mutect2, varscan2
- ACTRT3 | chr3:169764676 C>T | 3'Flank (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501238 G>C | 5'Flank (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2
- CANT1 | c.-1G>A | 5'UTR (SNP) | VAF 7/33 reads (21%) | catalogued as rs1005286177, COSV56604907; called by muse, mutect2, varscan2
- CDC42BPA | c.4791+5056C>T | Intron (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100504274; called by muse, mutect2
- HLA-DRB9 | n.201C>T | RNA (SNP) | VAF 31/89 reads (35%) | called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847207 C>A | 5'Flank (SNP) | VAF 49/451 reads (11%) | called by muse, varscan2
- LKAAEAR1 | c.*9G>A | 3'UTR (SNP) | VAF 8/23 reads (35%) | catalogued as COSV57478452, COSV57478731; called by muse, mutect2, varscan2
- POM121 | chr7:72949908 C>G | 3'Flank (SNP) | VAF 9/50 reads (18%) | catalogued as COSV99987914; called by muse, mutect2, varscan2
- PPP3R1 | chr2:68253037 G>A | 5'Flank (SNP) | VAF 17/38 reads (45%) | catalogued as COSV99310251; called by muse, mutect2, varscan2
- PXN | c.831+1670C>T | Intron (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- RAVER1 | c.1431+342C>G | Intron (SNP) | VAF 8/19 reads (42%) | catalogued as COSV53346427; called by muse, mutect2
- RPL31P57 | n.30G>A | RNA (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- RUNX1 | c.532+3044C>T | Intron (SNP) | VAF 17/63 reads (27%) | catalogued as rs763823959, COSV55867452; called by muse, mutect2, varscan2
- SNORD114-21 | n.64G>T | RNA (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2, varscan2
- SNORD116-7 | n.6G>A | RNA (SNP) | VAF 37/125 reads (30%) | catalogued as rs1182175970; called by muse, mutect2, varscan2
- SSPOP | n.6690C>T | RNA (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100022280; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 10/40 reads (25%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- TLE4 | c.936+216_936+254del | Intron (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- UNC5D | c.104-4839C>T | Intron (SNP) | VAF 9/39 reads (23%) | catalogued as COSV54770128; called by muse, mutect2, varscan2
- ZWINT | c.*89G>A | 3'UTR (SNP) | VAF 18/60 reads (30%) | catalogued as COSV59184849; called by muse, mutect2, varscan2
